Somatic mutation profile of tumor specimen C3L-01971-02 (aliquot CPT0108930009) from CPTAC case C3L-01971, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 66.7 years (24,359 days).
Specimen C3L-01971-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6a56481-6862-4874-9ea0-c3f375db81bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01971-31 (Blood Derived Normal), aliquot CPT0108360002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b4c5d3d-9a0f-47f8-99db-636a1c4dd242

The open-access MAF lists 70 somatic variants for this specimen: 41 protein-altering or splice-affecting, 17 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 17, Intron 7, Frame Shift Del 4, 5'UTR 3, Nonsense Mutation 3, 3'UTR 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 134/382 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.275_276del p.H92Rfs*11 | Frame Shift Del (DEL) | VAF 80/449 reads (18%) | catalogued as rs1555685156; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 92/490 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: pathogenic / likely pathogenic / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ACAN | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 52/414 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs539804190, COSV61360848; called by muse, mutect2, varscan2
- ADAMTS18 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 74/469 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as rs1458616586, COSV51423374; called by muse, mutect2, varscan2
- ANKRD24 | c.3091C>T p.R1031W | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs771211944, COSV53667982; called by muse, mutect2, varscan2
- ATM | c.317A>G p.K106R | Missense Mutation (SNP) | VAF 47/337 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs878853501, COSV53749541; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNG3 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.732); catalogued as rs746004181, COSV50065372; called by muse, mutect2, varscan2
- CDCA2 | c.2407G>T p.E803* | Nonsense Mutation (SNP) | VAF 30/204 reads (15%) | catalogued as rs1304050826; called by muse, mutect2, varscan2
- CDKN2A | c.181del p.E61Sfs*85 | Frame Shift Del (DEL) | VAF 76/266 reads (29%) | catalogued as COSV58682685, COSV58683250; called by mutect2, pindel*, varscan2
- CFAP206 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs757635858, COSV51532616; called by muse, mutect2, varscan2
- CFTR | c.3263A>G p.N1088S | Missense Mutation (SNP) | VAF 89/492 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0.021); catalogued as rs1199667380, COSV50054547; called by muse, mutect2, varscan2
- CLUAP1 | c.58C>T p.R20* | Nonsense Mutation (SNP) | VAF 28/234 reads (12%) | catalogued as rs759248659, COSV58892567; called by muse, mutect2, varscan2
- FIGNL1 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63553302; called by muse, mutect2, varscan2
- HYOU1 | c.2077C>T p.R693W | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as rs782191000; called by muse, mutect2, varscan2
- KCP | c.4202G>A p.R1401H (on ENST00000620378; = p.R1525H on NM_001366122.1) | Missense Mutation (SNP) | VAF 24/243 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs368547608; called by muse, mutect2
- NCAM1 | c.1814C>T p.T605M (on ENST00000316851 / NM_181351.5; = p.T595M on NM_000615.7) | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782353037, COSV57517108; called by muse, mutect2, varscan2
- PCDHA3 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 81/548 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.304); catalogued as rs781900612, COSV100974063; called by muse, mutect2, varscan2
- PCDHB3 | c.2171G>A p.R724H | Missense Mutation (SNP) | VAF 54/253 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.013); catalogued as COSV99166913; called by muse, mutect2, varscan2
- PCDHGA12 | c.1868C>T p.T623M | Missense Mutation (SNP) | VAF 32/388 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52744421; called by muse, mutect2
- RING1 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 53/316 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1204881780, COSV63002527; called by muse, mutect2, varscan2
- SSRP1 | c.680G>A p.G227D | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53479305; called by muse, mutect2, varscan2
- TSPYL1 | c.1078G>A p.G360R | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63994016; called by muse, mutect2, varscan2
- UTRN | c.3764G>A p.R1255Q | Missense Mutation (SNP) | VAF 16/227 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as rs752470080, COSV104423030; called by muse, mutect2
- ZNF160 | c.1766G>C p.G589A | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62001090; called by muse, mutect2, varscan2
- ACSM5 | c.833C>A p.A278E | Missense Mutation (SNP) | VAF 40/291 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ARID3C | c.706G>T p.G236C | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- CDK5RAP2 | c.643G>T p.V215F | Missense Mutation (SNP) | VAF 26/255 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); called by muse, mutect2
- CENPF | c.3065A>T p.K1022I | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.27); called by muse, mutect2
- CHRM4 | c.1278C>G p.C426W | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CLIP1 | c.3033+1G>T p.X1011_splice (on ENST00000620786 / NM_001247997.1; = p.X1000_splice on NM_002956.2) | Splice Site (SNP) | VAF 17/148 reads (11%) | called by muse, mutect2, varscan2
- IRS2 | c.2744G>A p.S915N | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KCTD19 | c.2593G>A p.V865M | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LTB4R | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 48/298 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- SETD1B | c.5285_5286del p.R1762Ifs*11 | Frame Shift Del (DEL) | VAF 39/229 reads (17%) | called by mutect2, pindel, varscan2
- SLC44A2 | c.254C>G p.P85R | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); called by muse, varscan2
- SPTAN1 | c.880C>T p.L294F | Missense Mutation (SNP) | VAF 91/546 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TIGD1 | c.445A>C p.K149Q | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- TRBV2 | c.22T>C p.W8R | Missense Mutation (SNP) | VAF 61/401 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ZDHHC13 | c.1481_1482del p.S494* | Frame Shift Del (DEL) | VAF 29/179 reads (16%) | called by mutect2, pindel, varscan2
- ZNF671 | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 15/70 reads (21%) | called by muse, mutect2, varscan2
- CFAP54 | c.3807A>G p.P1269= | Silent (SNP) | VAF 29/223 reads (13%) | called by muse, mutect2, varscan2
- IGHV3-66 | c.66G>A p.Q22= | Silent (SNP) | VAF 38/337 reads (11%) | catalogued as rs782393884; called by muse, mutect2, varscan2
- INSYN2B | c.165C>T p.D55= | Silent (SNP) | VAF 15/138 reads (11%) | catalogued as rs748170159; called by muse, mutect2, varscan2
- LAMB3 | c.387C>T p.A129= | Silent (SNP) | VAF 57/276 reads (21%) | catalogued as rs374988953; ClinVar: likely benign; called by muse, mutect2, varscan2
- MEGF10 | c.2181C>T p.Y727= | Silent (SNP) | VAF 20/226 reads (9%) | catalogued as rs757670476, COSV57244980; called by muse, mutect2
- PDZD2 | c.7215C>T p.S2405= | Silent (SNP) | VAF 23/145 reads (16%) | catalogued as rs768918693, COSV56876735; called by muse, mutect2, varscan2
- PLEKHH1 | c.1104T>G p.A368= | Silent (SNP) | VAF 41/292 reads (14%) | called by muse, mutect2, varscan2
- PLXNB1 | c.2550C>T p.P850= | Silent (SNP) | VAF 15/149 reads (10%) | catalogued as rs774347842; called by muse, mutect2, varscan2
- RAB36 | c.183G>T p.S61= | Silent (SNP) | VAF 22/86 reads (26%) | called by muse, varscan2
- SBF1 | c.1401C>T p.V467= | Silent (SNP) | VAF 12/181 reads (7%) | called by muse, mutect2
- SCN11A | c.2094C>A p.V698= | Silent (SNP) | VAF 48/204 reads (24%) | called by muse, mutect2, varscan2
- SCN8A | c.1539G>A p.E513= | Silent (SNP) | VAF 40/113 reads (35%) | called by muse, mutect2, varscan2
- SHOX | c.480C>T p.R160= | Silent (SNP) | VAF 40/210 reads (19%) | called by muse, mutect2, varscan2
- SLC1A4 | c.1566C>G p.A522= | Silent (SNP) | VAF 18/155 reads (12%) | called by muse, mutect2, varscan2
- SLC35B2 | c.273G>A p.E91= | Silent (SNP) | VAF 59/238 reads (25%) | called by muse, mutect2, varscan2
- SOAT2 | c.1320C>T p.F440= | Silent (SNP) | VAF 111/319 reads (35%) | catalogued as rs201335480, COSV56859558; called by muse, mutect2, varscan2
- TRIM9 | c.1836C>T p.D612= | Silent (SNP) | VAF 29/356 reads (8%) | catalogued as rs757270399, COSV53624076; called by muse, mutect2
- BHLHE40 | c.80+40G>C | Intron (SNP) | VAF 7/187 reads (4%) | called by muse, mutect2
- COLQ | c.1196-18C>T | Intron (SNP) | VAF 56/364 reads (15%) | catalogued as rs1297760071; called by muse, mutect2, varscan2
- CSF2RA | c.-142G>A | 5'UTR (SNP) | VAF 26/357 reads (7%) | catalogued as rs1395722632; called by muse, mutect2
- MAP4 | c.1999+3249_1999+3251del | Intron (DEL) | VAF 23/188 reads (12%) | called by mutect2, pindel, varscan2
- NDUFS7 | c.228+34G>A | Intron (SNP) | VAF 39/202 reads (19%) | catalogued as rs1190066432; called by muse, mutect2, varscan2
- NFASC | c.*82G>A | 3'UTR (SNP) | VAF 48/211 reads (23%) | catalogued as rs541890830, COSV58370252; called by muse, mutect2, varscan2
- PENK | c.138+1797G>A | Intron (SNP) | VAF 41/169 reads (24%) | called by muse, mutect2, varscan2
- PPP5D1 | n.418G>A | RNA (SNP) | VAF 18/241 reads (7%) | catalogued as rs770810435, COSV101330940; called by muse, mutect2
- RUNX1T1 | c.1280-3853A>G | Intron (SNP) | VAF 53/235 reads (23%) | called by muse, mutect2, varscan2
- SELP | c.-2A>G | 5'UTR (SNP) | VAF 18/216 reads (8%) | called by muse, mutect2
- TOP1MT | c.360+1048C>T | Intron (SNP) | VAF 22/280 reads (8%) | catalogued as rs921883903; called by muse, mutect2
- USP14 | c.-40C>T | 5'UTR (SNP) | VAF 29/131 reads (22%) | catalogued as rs907774651; called by muse, mutect2, varscan2
